FM case AD6878 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/28f5ff33-7cc8-458d-a782-716fe8e47e72

Male, 36.6 years: Melanoma, NOS (ICD-O-3 8720/3) of the eye; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
